MMRF case MMRF_2488 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6ba33f7b-c952-4c39-b7b7-0599f5109263

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.9 years (19,331 days); ISS stage: III; Days to last known disease status: 728 days (2.0 years); Days to last follow up: 728 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 90 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 188 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 243 days; Days to treatment end: 245 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 246 days; Days to treatment end: 246 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 248 days; Days to treatment end: 248 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 346 days; Days to treatment end: 402 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 430 days (1.2 years); Days to treatment end: 609 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 430 days (1.2 years); Days to treatment end: 640 days (1.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): M Protein 6.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.076 mg/dL; Immunoglobulin G 86.8 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 7.81 µg/mL; Lactate Dehydrogenase 8.45 µkat/L; Hemoglobin 4.84 mmol/L; Leukocytes 13.8 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 11.5 g/dL; Glucose 5.28 mmol/L; C-Reactive Protein 7.7 mg/dL.
- Day 105 (ECOG 1): M Protein 2.85 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.049 mg/dL; Immunoglobulin G 39.5 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.37 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 345 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 8.7 g/dL; Glucose 4.73 mmol/L.
- Day 191 (ECOG 1): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.122 mg/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 320 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.08 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 4.29 mmol/L.
- Day 283 (ECOG 0): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.998 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 7.99 g/L; Immunoglobulin A 2.97 g/L; Immunoglobulin M 0.72 g/L; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 4.68 mmol/L.
- Day 374 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 4.56 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.35 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.57 mmol/L.
- Day 458 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 5.3 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.46 mmol/L.
- Day 542 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 4.46 g/L; Immunoglobulin A 1.9 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.38 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 10.5 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.23 mmol/L.
- Day 646 (ECOG 4): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 4.53 g/L; Immunoglobulin A 2.23 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.54 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 5.97 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Total Protein 6.5 g/dL; Glucose 4.9 mmol/L.
- Day 728 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 5.36 g/L; Immunoglobulin A 2.57 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 1.73 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 4.57 mmol/L.

Other clinical attributes
- Day 1: Weight: 88 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2488_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2488_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
